Somatic mutation profile of tumor specimen C3L-03266-01 (aliquot CPT0189460006) from CPTAC case C3L-03266, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.8 years (22,583 days).
Specimen C3L-03266-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea1f9b14-b04f-4125-bb17-2d179a39d88c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03266-31 (Blood Derived Normal), aliquot CPT0190220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6c1ad70-3dbf-438b-b8c1-9ec52acbd162

The open-access MAF lists 65 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Nonsense Mutation 6, In Frame Del 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55945426; called by muse, mutect2, varscan2
- ABCC1 | c.2696G>C p.G899A | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as rs1353662688; called by muse, mutect2, varscan2
- AP3B2 | c.2516C>A p.A839D (on ENST00000261722; = p.A833D on NM_004644.5) | Missense Mutation (SNP) | VAF 41/474 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.903); catalogued as rs756273764; called by muse, mutect2
- ARHGAP4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380501731, COSV100604214; called by muse, mutect2, varscan2
- BMP5 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 59/167 reads (35%) | catalogued as rs1396089139, COSV63701194; called by muse, mutect2, varscan2
- CALN1 | c.568C>T p.R190W (on ENST00000329008 / NM_001017440.3; = p.R232W on NM_031468.4) | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774961183, COSV61139437; called by muse, mutect2, varscan2
- CES1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 120/624 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs563293177, COSV100828653, COSV62086839; called by muse, mutect2, varscan2
- CT47B1 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 373/918 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as rs749011334, COSV64890387; called by muse, mutect2, varscan2
- CTPS2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1276539401; called by muse, mutect2, varscan2
- CYP2F1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs374908629; called by muse, mutect2, varscan2
- DCAF4L2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV60477788, COSV60478000; called by muse, mutect2, varscan2
- DOCK3 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | catalogued as COSV56532621, COSV99808755; called by muse, mutect2, varscan2
- FAM205A | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778196529, COSV66490141; called by muse, mutect2, varscan2
- HAVCR1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs114193906, COSV59400630; called by muse, mutect2, varscan2
- HCN1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs541911994, COSV57491575; called by muse, mutect2, varscan2
- IARS1 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs766050617; called by muse, mutect2, varscan2
- KCNC4 | c.26_28del p.S9del | In Frame Del (DEL) | VAF 21/96 reads (22%) | catalogued as rs748484156; called by pindel, varscan2
- KEL | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 151/622 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs766803262, CM1313988; called by muse, mutect2, varscan2
- KEL | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.94); catalogued as rs772712802, COSV62336904; called by muse, mutect2, varscan2
- KIAA1549L | c.3242G>A p.R1081Q (on ENST00000321505; = p.R1378Q on NM_012194.3) | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1459374986; called by muse, mutect2, varscan2
- KRT33A | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773713433; called by muse, mutect2, varscan2
- NFE2L3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs566561270, COSV50228075; called by muse, mutect2, varscan2
- NPC1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555633697, CM015181, CM032640, COSV52577815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHRF1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 154/424 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs748606414, COSV52750870; called by muse, mutect2, varscan2
- PRRC2A | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 169/374 reads (45%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs777743606; called by muse, mutect2, varscan2
- RPL7A | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs782417066, COSV59299052; called by muse, mutect2, varscan2
- RRBP1 | c.756_785del p.T255_G264del | In Frame Del (DEL) | VAF 75/248 reads (30%) | catalogued as rs780620529; called by muse*, mutect2
- SH2D4B | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs776769242; called by muse, mutect2, varscan2
- TRPM3 | c.3818G>A p.R1273H (on ENST00000357533 / NM_001366142.2; = p.R1128H on NM_020952.6) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.223); catalogued as rs769442758, COSV62596790; called by muse, mutect2, varscan2
- ADAMTS16 | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CCDC150 | c.2167G>T p.D723Y | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DNAH3 | c.11001G>A p.W3667* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- GABRA1 | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GABRA6 | c.1285T>A p.F429I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV1-17 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 101/406 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, varscan2
- INPP5J | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 99/261 reads (38%) | called by muse, mutect2, varscan2
- MSH4 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUF2 | c.610G>C p.V204L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTEN | c.584_585dup p.H196Ffs*4 | Frame Shift Ins (INS) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- RNASE10 | c.348_351del p.D116Efs*6 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- SAC3D1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SERPINB10 | c.32T>A p.F11Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC66A1 | c.647_649del p.S216del | In Frame Del (DEL) | VAF 44/152 reads (29%) | called by mutect2, pindel, varscan2
- SMC1B | c.2867del p.G956Efs*22 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- STOML1 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- UTP18 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ZNF445 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 82/208 reads (39%) | called by muse, mutect2, varscan2
- AC138647.1 | c.159C>G p.G53= | Silent (SNP) | VAF 135/346 reads (39%) | called by muse, mutect2, varscan2
- ASPHD1 | c.993G>A p.E331= | Silent (SNP) | VAF 49/141 reads (35%) | called by muse, mutect2, varscan2
- GLUD2 | c.582C>T p.T194= | Silent (SNP) | VAF 107/250 reads (43%) | catalogued as rs752231129, COSV100046910, COSV60151158; called by muse, mutect2, varscan2
- ICAM2 | c.696G>T p.S232= | Silent (SNP) | VAF 85/227 reads (37%) | catalogued as rs774163017, COSV99856909; called by muse, mutect2, varscan2
- IQSEC3 | c.1398C>T p.D466= (on ENST00000538872 / NM_001170738.2; = p.D163= on NM_015232.1) | Silent (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- LRP2 | c.666C>T p.C222= | Silent (SNP) | VAF 114/158 reads (72%) | catalogued as rs746905339, COSV99790512; called by muse, mutect2, varscan2
- MAP2K3 | c.381C>T p.Y127= (on ENST00000342679 / NM_145109.3; = p.Y98= on NM_002756.4) | Silent (SNP) | VAF 48/336 reads (14%) | catalogued as rs753144703, COSV57564464, COSV57578769; called by muse, mutect2
- MYO16 | c.4014C>T p.D1338= | Silent (SNP) | VAF 58/412 reads (14%) | catalogued as COSV62759633; called by muse, mutect2, varscan2
- PRKCE | c.1551A>G p.T517= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV60329893; called by muse, mutect2, varscan2
- PTK2B | c.1905C>T p.I635= | Silent (SNP) | VAF 128/412 reads (31%) | catalogued as rs1297144875, COSV57761277; called by muse, mutect2, varscan2
- SLC22A8 | c.447C>A p.R149= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, varscan2
- TMEM132A | c.2772C>T p.P924= (on ENST00000453848 / NM_178031.3; = p.P925= on NM_017870.4) | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- TRAV22 | c.240C>T p.S80= | Silent (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- TUT7 | c.2145A>G p.E715= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- CD300E | c.-22C>T | 5'UTR (SNP) | VAF 40/140 reads (29%) | catalogued as rs375091102, COSV100151104; called by muse, mutect2, varscan2
- IGSF1 | chrX:131289403 C>T | 5'Flank (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- MORN5 | c.439+27G>A | Intron (SNP) | VAF 58/147 reads (39%) | catalogued as rs1311625055, COSV65649017; called by muse, mutect2, varscan2
- STXBP2 | c.1697-40C>T | Intron (SNP) | VAF 48/178 reads (27%) | catalogued as rs1405515663; called by muse, mutect2, varscan2
